Somatic mutation profile of tumor specimen TCGA-A3-3382-01A (aliquot TCGA-A3-3382-01A-01D-0966-08) from TCGA case TCGA-A3-3382, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 69.0 years (25,207 days).
Specimen TCGA-A3-3382-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f0d107d-7d22-4b35-bf81-95158f35c633.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3382-11A (Solid Tissue Normal), aliquot TCGA-A3-3382-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8759844-7d24-4470-8aef-18ec68292653

The open-access MAF lists 102 somatic variants for this specimen: 82 protein-altering or splice-affecting, 15 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 15, Nonsense Mutation 7, Frame Shift Del 6, In Frame Del 3, RNA 3, Splice Site 2, Intron 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.343C>A p.H115N | Missense Mutation (SNP) | VAF 115/190 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as CD141839, CM961423, CM982005, COSV56545369, COSV56546151, COSV56556158, COSV56571206; called by muse, mutect2, varscan2
- AICDA | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV57563789, COSV57564692; called by muse, mutect2, varscan2
- ATP1A1 | c.1171A>G p.M391V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as rs1252478023; called by muse, mutect2, varscan2
- C1orf94 | c.1234C>T p.R412* (on ENST00000488417 / NM_001134734.2; = p.R222* on NM_032884.5) | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as rs775448857, COSV64914334; called by muse, mutect2
- CASP10 | c.625C>A p.Q209K | Missense Mutation (SNP) | VAF 119/336 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs895371405, COSV53778786; called by muse, mutect2, varscan2
- CTSE | c.517A>T p.S173C (on ENST00000360218; = p.S168C on NM_001910.4) | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63059956; called by muse, mutect2
- DNAH3 | c.1961C>A p.S654Y | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.88); PolyPhen benign (0.011); catalogued as COSV54521719, COSV54532850; called by muse, mutect2, varscan2
- E2F8 | c.2137G>A p.G713R | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.657); catalogued as rs754334957, COSV100001551, COSV51463335; called by muse, mutect2, varscan2
- FBF1 | c.2424G>A p.M808I (on ENST00000586717; = p.M822I on NM_001319193.1) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs781053338; called by muse, varscan2
- GOLIM4 | c.1013A>C p.E338A | Missense Mutation (SNP) | VAF 77/151 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs1358541995, COSV58327947; called by muse, mutect2, varscan2
- KIF16B | c.3169C>G p.Q1057E | Missense Mutation (SNP) | VAF 126/330 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.036); catalogued as COSV61716773; called by muse, mutect2, varscan2
- LRRC32 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs370963014, COSV99477004; called by muse, mutect2, varscan2
- MAP2K7 | c.1156C>A p.L386M | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.251); catalogued as rs764054804, COSV67609313; called by muse, mutect2, varscan2
- MFSD6 | c.835T>C p.Y279H | Missense Mutation (SNP) | VAF 143/374 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs777184056; called by muse, mutect2, varscan2
- MSC | c.371G>C p.S124T | Missense Mutation (SNP) | VAF 69/89 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV57696553; called by muse, mutect2, varscan2
- NCOA1 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs371834198, COSV56055132; called by muse, mutect2, varscan2
- OR2L8 | c.180C>G p.F60L | Missense Mutation (SNP) | VAF 332/1171 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as COSV61728485; called by muse, mutect2, varscan2
- OR2T12 | c.379C>G p.P127A | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1207273678, COSV99040529; called by muse, mutect2, varscan2
- PBRM1 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 59/92 reads (64%) | catalogued as COSV56264253; called by muse, mutect2, varscan2
- SALL3 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.091); catalogued as COSV73306060; called by muse, mutect2, varscan2
- SCNN1A | c.1757G>A p.R586Q | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.163); catalogued as rs545954539; called by muse, mutect2, varscan2
- ZNF347 | c.1628G>T p.C543F | Missense Mutation (SNP) | VAF 140/368 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100498311; called by muse, mutect2, varscan2
- ZNF451 | c.2330A>C p.K777T | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV62597730; called by muse, mutect2, varscan2
- A1CF | c.867+1del p.X289_splice | Splice Site (DEL) | VAF 29/130 reads (22%) | called by mutect2, pindel, varscan2
- AADACL3 | c.991G>C p.D331H | Missense Mutation (SNP) | VAF 53/246 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ABCA12 | c.2680C>A p.L894I (on ENST00000272895 / NM_173076.3; = p.L576I on NM_015657.3) | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ABCA2 | c.704C>G p.S235C (on ENST00000614293; = p.S205C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- ADAMTS7 | c.3497C>G p.A1166G | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1147_1156del p.V383Wfs*18 | Frame Shift Del (DEL) | VAF 53/194 reads (27%) | called by mutect2, pindel, varscan2
- ANGPTL7 | c.348del p.A117Hfs*105 | Frame Shift Del (DEL) | VAF 21/130 reads (16%) | called by mutect2, pindel, varscan2
- ANKRD44 | c.1209dup p.F404Ifs*14 | Frame Shift Ins (INS) | VAF 58/209 reads (28%) | called by mutect2, pindel, varscan2
- ARNTL | c.91A>G p.S31G | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATPAF2 | c.480_482del p.I162del | In Frame Del (DEL) | VAF 25/124 reads (20%) | called by mutect2, pindel, varscan2
- B9D1 | c.365T>G p.F122C | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C16orf71 | c.149A>C p.E50A | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDK2 | c.492_495delinsCA p.L166Vfs*6 | Frame Shift Del (DEL) | VAF 43/111 reads (39%) | called by pindel, varscan2*
- CEP83 | c.700T>A p.L234I | Missense Mutation (SNP) | VAF 136/381 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD5 | c.5303T>A p.L1768H | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CPLX2 | c.222G>T p.K74N | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DCDC1 | c.2791G>T p.E931* (on ENST00000597505 / NM_001367979.1; = p.E38* on NM_020869.3) | Nonsense Mutation (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- DMD | c.9334C>A p.L3112I | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT tolerated (0.78); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- DMXL2 | c.3772G>C p.G1258R | Missense Mutation (SNP) | VAF 160/259 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJB4 | c.329T>C p.I110T | Missense Mutation (SNP) | VAF 66/252 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ENHO | c.65T>G p.L22W | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ENO1 | c.495G>T p.M165I | Missense Mutation (SNP) | VAF 58/269 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- FRS2 | c.505del p.S169Lfs*10 | Frame Shift Del (DEL) | VAF 76/193 reads (39%) | called by mutect2, pindel, varscan2
- GULP1 | c.844-1G>A p.X282_splice | Splice Site (SNP) | VAF 54/151 reads (36%) | called by muse, mutect2, varscan2
- HFM1 | c.1753T>C p.Y585H | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HSP90AB1 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- HSPA12A | c.1689G>C p.W563C | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HTT | c.866_878del p.S289Mfs*4 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | called by mutect2, pindel, varscan2
- IPP | c.1333_1341del p.I445_N447del | In Frame Del (DEL) | VAF 37/100 reads (37%) | called by mutect2, pindel, varscan2
- KAT6B | c.2557T>A p.Y853N | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- LDHAL6B | c.37A>T p.R13* | Nonsense Mutation (SNP) | VAF 16/24 reads (67%) | called by muse, mutect2
- MAP4 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 120/180 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- NF1 | c.8226C>G p.Y2742* (on ENST00000358273 / NM_001042492.3; = p.Y2721* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 87/227 reads (38%) | called by muse, mutect2, varscan2
- OR10S1 | c.38C>A p.T13K | Missense Mutation (SNP) | VAF 67/277 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTOF | c.1735G>C p.D579H | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PDLIM4 | c.220G>T p.D74Y | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.955); called by muse, mutect2
- PHF12 | c.700A>G p.T234A | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- PHTF1 | c.1254G>T p.E418D | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (0.89); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- POLK | c.1528G>A p.G510S | Missense Mutation (SNP) | VAF 133/305 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNH1 | c.614A>G p.K205R | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.73); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RSRP1 | c.295_300del p.G99_F100del | In Frame Del (DEL) | VAF 22/61 reads (36%) | called by mutect2, pindel, varscan2
- SCN10A | c.1402G>T p.E468* | Nonsense Mutation (SNP) | VAF 79/253 reads (31%) | called by muse, mutect2, varscan2
- SNED1 | c.704A>G p.D235G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); called by muse, mutect2
- SOHLH1 | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SPEF2 | c.2274del p.K758Nfs*27 | Frame Shift Del (DEL) | VAF 44/171 reads (26%) | called by mutect2, pindel, varscan2
- STRBP | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 86/158 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TARS2 | c.1645G>A p.G549S | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TCOF1 | c.570G>T p.M190I | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- TNK1 | c.1603G>T p.G535C (on ENST00000576812 / NM_001251902.2; = p.G530C on NM_003985.5) | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- TRPC7 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 203/444 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- TTN | c.13945G>A p.A4649T (on ENST00000591111; = p.A3722T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/59 reads (31%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TUBB1 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- UBA7 | c.1844C>A p.A615D | Missense Mutation (SNP) | VAF 77/125 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USH2A | c.3171A>C p.Q1057H | Missense Mutation (SNP) | VAF 59/230 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UTRN | c.2560A>G p.K854E | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- WDTC1 | c.838G>C p.G280R | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WIPI2 | c.1345A>G p.M449V | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF292 | c.7543C>T p.Q2515* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- ZUP1 | c.784A>G p.K262E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- CYFIP2 | c.1383G>A p.Q461= | Silent (SNP) | VAF 55/158 reads (35%) | called by muse, mutect2, varscan2
- EHD3 | c.939T>C p.S313= | Silent (SNP) | VAF 122/308 reads (40%) | catalogued as rs1292812843; called by muse, mutect2, varscan2
- FOXK1 | c.1107C>G p.S369= | Silent (SNP) | VAF 42/241 reads (17%) | catalogued as rs1293216391; called by muse, mutect2, varscan2
- GALNT3 | c.1593T>A p.I531= | Silent (SNP) | VAF 44/123 reads (36%) | called by muse, mutect2, varscan2
- GLCCI1 | c.1482T>G p.V494= | Silent (SNP) | VAF 279/790 reads (35%) | called by muse, mutect2, varscan2
- MAVS | c.876C>T p.N292= | Silent (SNP) | VAF 44/124 reads (35%) | called by muse, mutect2, varscan2
- MRM2 | c.645A>T p.V215= | Silent (SNP) | VAF 101/281 reads (36%) | called by muse, mutect2, varscan2
- NF1 | c.2442G>A p.K814= | Silent (SNP) | VAF 21/98 reads (21%) | called by muse, mutect2, varscan2
- OR2T27 | c.696G>A p.E232= | Silent (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- PLTP | c.1023C>A p.G341= | Silent (SNP) | VAF 30/173 reads (17%) | called by muse, mutect2, varscan2
- SMC3 | c.174A>G p.P58= | Silent (SNP) | VAF 50/128 reads (39%) | catalogued as COSV100699965; called by muse, mutect2, varscan2
- SNRPB | c.9G>T p.V3= | Silent (SNP) | VAF 56/151 reads (37%) | called by muse, mutect2, varscan2
- SOHLH1 | c.963G>T p.G321= | Silent (SNP) | VAF 32/56 reads (57%) | called by muse, mutect2, varscan2
- VPS11 | c.186C>T p.A62= (on ENST00000620429; = p.A606= on NM_021729.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 90/372 reads (24%) | catalogued as rs781935851; called by muse, mutect2, varscan2
- WDFY3 | c.2028G>C p.V676= | Silent (SNP) | VAF 48/131 reads (37%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502878 T>C | 5'Flank (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- CERS6 | c.1002+589C>T | Intron (SNP) | VAF 53/170 reads (31%) | called by muse, mutect2, varscan2
- FOLH1B | n.1680dup | RNA (INS) | VAF 33/198 reads (17%) | called by mutect2, pindel, varscan2
- MIR498 | n.59_60del | RNA (DEL) | VAF 44/278 reads (16%) | called by pindel, varscan2
- SNORD52 | n.15C>T | RNA (SNP) | VAF 22/80 reads (28%) | called by muse, mutect2, varscan2
